Somatic mutation profile of tumor specimen C3L-07558-01 (aliquot CPT0429570006) from CPTAC case C3L-07558, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 46.9 years (17,134 days).
Specimen C3L-07558-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 592b58ef-71e3-4d67-a231-14aee669548f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07558-31 (Blood Derived Normal), aliquot CPT0429720004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43be665a-2d8d-4492-8d31-45fe754c4228

The open-access MAF lists 154 somatic variants for this specimen: 116 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 35, Nonsense Mutation 6, Intron 2, 3'UTR 1, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 120/596 reads (20%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- MYH7 | c.4066G>A p.E1356K | Missense Mutation (SNP) | VAF 32/572 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs727503246, CM042422, CM1313302, COSV62515965; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- RNF43 | c.257A>G p.H86R | Missense Mutation (SNP) | VAF 14/228 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV68457845, COSV68459198; called by muse, mutect2
- ABCC12 | c.2208C>T p.I736= | Splice Region (SNP) | VAF 33/297 reads (11%) | catalogued as rs747006466; called by muse, mutect2, varscan2
- AC092835.1 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1370425175; called by muse, mutect2
- ADAMTS1 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 29/660 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1033644530; called by muse, mutect2
- ADAMTS10 | c.3149C>T p.T1050M | Missense Mutation (SNP) | VAF 46/528 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs916677846; called by muse, mutect2
- ADARB1 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 51/406 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1484574248; called by muse, mutect2, varscan2
- ANKRD11 | c.7855G>A p.V2619M | Missense Mutation (SNP) | VAF 30/422 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56369809; called by muse, mutect2
- ARID5B | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 21/333 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54420890, COSV54432885; called by muse, mutect2
- ARSF | c.1297C>A p.L433M | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1359934372; called by muse, mutect2
- ATP12A | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 21/289 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745443085, COSV54512186; called by muse, mutect2
- BDKRB1 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 36/621 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as rs891701156, COSV53705266; called by muse, mutect2
- CHRNA7 | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 50/1278 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs760406704; called by muse, mutect2
- CHST13 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV60043162; called by muse, mutect2
- COL5A1 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as CM994120, COSV100879925; called by muse, mutect2
- DCLK2 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 51/499 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770718037; called by muse, mutect2, varscan2
- DDIT4L | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 37/366 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs183155282; called by muse, mutect2, varscan2
- EPN1 | c.856G>A p.V286I (on ENST00000270460 / NM_001321263.1; = p.V261I on NM_013333.3) | Missense Mutation (SNP) | VAF 34/790 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs770482611, COSV50038038; called by muse, mutect2
- ERBB3 | c.3701C>T p.S1234F | Missense Mutation (SNP) | VAF 62/596 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV57247135, COSV57248025, COSV57256413; called by muse, mutect2, varscan2
- FAM50A | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 20/558 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50130720; called by muse, mutect2
- FAT1 | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 46/698 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs536104649, COSV71674334; called by muse, mutect2
- FBXO24 | c.1505C>T p.P502L (on ENST00000241071 / NM_033506.3; = p.P540L on NM_012172.5) | Missense Mutation (SNP) | VAF 21/623 reads (3%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as COSV53830621, COSV99575790; called by muse, mutect2
- FZR1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs768044432, COSV100553539; called by muse, mutect2
- GALK1 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 41/529 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs145837971; called by muse, mutect2
- GCM2 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 35/379 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs748810891; called by muse, mutect2
- GOLIM4 | c.421A>T p.K141* | Nonsense Mutation (SNP) | VAF 25/462 reads (5%) | catalogued as COSV58327755; called by muse, mutect2
- H2BE1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 58/618 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV99733881; called by muse, mutect2
- HDGFL2 | c.1411G>A p.V471M | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as rs779077438, COSV56683075; called by muse, mutect2
- IGKV4-1 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 32/385 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779070170; called by muse, mutect2
- KCND1 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 49/440 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as rs1358088607; called by muse, mutect2, varscan2
- KCND1 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 61/665 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs1352604431, COSV54416262; called by muse, mutect2
- KIF3C | c.1891T>C p.Y631H | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV53102658; called by muse, mutect2
- KMT2B | c.7531C>T p.R2511W | Missense Mutation (SNP) | VAF 16/464 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55820488; called by muse, mutect2
- LAMA5 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 40/535 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs531045232, COSV53352015, COSV53369863; called by muse, mutect2
- MANEA | c.1273C>A p.L425I | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as COSV100721471; called by muse, mutect2, varscan2
- MTOR | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 25/336 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1235010967, COSV63869536; called by muse, mutect2
- MXRA5 | c.6530G>A p.R2177H | Missense Mutation (SNP) | VAF 56/528 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs773254958, COSV54243733; called by muse, mutect2, varscan2
- MYH2 | c.3853C>T p.R1285C | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs374494789; called by muse, mutect2, varscan2
- MYLK2 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 45/385 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs763678910, COSV65659083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOS1 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1308404670, COSV57610968; called by muse, mutect2, varscan2
- OR51M1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 48/480 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs372583895, COSV60784593, COSV60785027; called by muse, mutect2, varscan2
- OR6T1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 40/502 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs749592607, COSV100189714, COSV58308535; called by muse, mutect2
- PCDHB4 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.341); catalogued as COSV52027047; called by muse, mutect2
- PCDHGA3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 20/482 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.382); catalogued as COSV53894034; called by muse, mutect2
- PCDHGB5 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 56/596 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as rs1561672586; called by muse, mutect2
- PER2 | c.3428C>T p.A1143V | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as rs760985489, COSV54524195, COSV54527157; called by muse, mutect2, varscan2
- PGM5 | c.1216A>G p.I406V | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as rs1554686929; called by muse, mutect2
- PPP2R5B | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 38/478 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.657); catalogued as rs887668274, COSV99375846; called by muse, mutect2
- PRPS1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 51/510 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV65054190; called by muse, mutect2, varscan2
- RBMS1 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 35/316 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV62356705; called by muse, mutect2, varscan2
- RFTN1 | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 43/249 reads (17%) | catalogued as rs754652628, COSV61918069; called by muse, mutect2, varscan2
- RRN3 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs773979584; called by muse, mutect2
- RYR1 | c.3442G>A p.V1148I | Missense Mutation (SNP) | VAF 38/493 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.917); catalogued as rs201174268; ClinVar: uncertain significance; called by muse, mutect2
- SF3B5 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 16/349 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1246238851; called by muse, mutect2
- SHANK1 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 77/926 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs368927877, COSV53250415; called by muse, mutect2
- SIAH3 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs761653065, COSV68552728; called by muse, mutect2
- SLC12A9 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 37/498 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.67); catalogued as rs143663491; called by muse, mutect2
- SLC9A2 | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as rs751114161, COSV99295718; called by muse, mutect2
- SPAM1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 37/446 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.065); catalogued as COSV99773058; called by muse, mutect2
- SPRED3 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 147/646 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100634310; called by muse, varscan2
- SPTBN4 | c.1588C>T p.R530* | Nonsense Mutation (SNP) | VAF 122/565 reads (22%) | catalogued as rs751664387, COSV100151973; called by muse, mutect2, varscan2
- STRA6 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs931369498, COSV60584753; called by muse, mutect2
- SYTL2 | c.1241C>G p.S414C | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs780473376, COSV60357783; called by muse, mutect2
- TAX1BP1 | c.699G>C p.Q233H | Missense Mutation (SNP) | VAF 21/369 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1316590860; called by muse, mutect2
- TCERG1L | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 22/543 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as rs1354612429; called by muse, mutect2
- TMEM26 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 40/413 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs765185921; called by muse, mutect2, varscan2
- TMEM41A | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1040634399; called by muse, mutect2
- TRPC3 | c.275G>A p.R92H (on ENST00000379645 / NM_001366479.2; = p.R19H on NM_003305.2) | Missense Mutation (SNP) | VAF 32/512 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); catalogued as COSV53380068; called by muse, mutect2
- UGT3A2 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 42/538 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as rs199567567; called by muse, mutect2
- VASH2 | c.925C>T p.R309W (on ENST00000517399 / NM_001301056.2; = p.R265W on NM_024749.5) | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs779122598, COSV55117355; called by muse, mutect2
- WWC3 | c.1409C>T p.T470M | Missense Mutation (SNP) | VAF 43/859 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765649211; called by muse, mutect2
- XPO5 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754531009; called by muse, mutect2
- ZIC1 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 29/871 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV51550495, COSV99291858; called by muse, mutect2
- AAMP | c.1185C>G p.D395E | Missense Mutation (SNP) | VAF 50/620 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ABHD16B | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 50/772 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.014); called by muse, mutect2
- AL117348.2 | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 40/540 reads (7%) | PolyPhen benign (0.057); called by muse, mutect2
- AMOTL1 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 19/324 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2
- AMPD3 | c.732C>A p.H244Q (on ENST00000396553 / NM_001025389.2; = p.H253Q on NM_000480.3) | Missense Mutation (SNP) | VAF 46/551 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- ARAP3 | c.3185G>A p.S1062N | Missense Mutation (SNP) | VAF 31/508 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2
- ARHGEF17 | c.2268C>A p.D756E | Missense Mutation (SNP) | VAF 47/492 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- BICRAL | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 20/484 reads (4%) | called by muse, mutect2
- C16orf96 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 62/714 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2
- CACNA1S | c.4211C>A p.A1404D | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2
- CHST7 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 71/579 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CHST9 | c.1079G>T p.C360F | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DEF6 | c.1459G>C p.A487P | Missense Mutation (SNP) | VAF 54/530 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- DNAH12 | c.1203T>A p.H401Q | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUOXA2 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.146); called by muse, mutect2
- GLUL | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 13/251 reads (5%) | called by muse, mutect2
- HECTD4 | c.5405A>G p.Q1802R | Missense Mutation (SNP) | VAF 26/389 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HERC1 | c.9231G>T p.W3077C | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCNK15 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 54/545 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KIAA1109 | c.14380A>G p.S4794G | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.138); called by muse, mutect2
- MCOLN3 | c.318T>G p.Y106* | Nonsense Mutation (SNP) | VAF 16/393 reads (4%) | called by muse, mutect2
- MEPE | c.350A>T p.Y117F | Missense Mutation (SNP) | VAF 41/418 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- MUC16 | c.1943C>A p.P648Q | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- NAT16 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 18/624 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.142); called by muse, mutect2
- PACS2 | c.1097G>A p.S366N | Missense Mutation (SNP) | VAF 58/527 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PCDH19 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 54/691 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); called by muse, mutect2
- PCNT | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 16/389 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- PDPR | c.1088C>A p.P363Q | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PKDREJ | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 40/453 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2
- PNMA8B | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 72/721 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.157); called by muse, mutect2
- PPP1R18 | c.1574G>T p.C525F | Missense Mutation (SNP) | VAF 30/602 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2
- PSD | c.785del p.P262Hfs*32 | Frame Shift Del (DEL) | VAF 58/614 reads (9%) | called by mutect2, pindel
- RALGAPA1 | c.1345A>G p.M449V | Missense Mutation (SNP) | VAF 13/355 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2
- ROM1 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- SSTR1 | c.734T>G p.L245R | Missense Mutation (SNP) | VAF 19/575 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- TRMO | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TXNDC15 | c.385A>T p.S129C | Missense Mutation (SNP) | VAF 37/431 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by muse, mutect2
- UBR1 | c.4064T>A p.L1355Q | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- UNC13A | c.2773G>A p.A925T | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); called by muse, mutect2
- VPS35 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 38/395 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2
- ZFPM2 | c.3299A>T p.Q1100L | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.236); called by muse, mutect2
- ZMAT1 | c.1853A>G p.K618R | Missense Mutation (SNP) | VAF 18/467 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2
- ABHD2 | c.1206C>T p.N402= | Silent (SNP) | VAF 46/560 reads (8%) | catalogued as rs746027991, COSV61776419; called by muse, mutect2
- ADAD1 | c.636C>T p.I212= | Silent (SNP) | VAF 20/210 reads (10%) | catalogued as rs756826832, COSV56644130; called by muse, mutect2
- ADRA1B | c.1464C>T p.D488= | Silent (SNP) | VAF 22/650 reads (3%) | catalogued as rs1303677234; called by muse, mutect2
- ANAPC2 | c.1836C>T p.P612= | Silent (SNP) | VAF 30/538 reads (6%) | catalogued as rs747655033, COSV100119265; called by muse, mutect2
- CCDC8 | c.426C>T p.S142= | Silent (SNP) | VAF 57/783 reads (7%) | catalogued as COSV56772745; called by muse, mutect2
- CCNB3 | c.2676C>T p.F892= | Silent (SNP) | VAF 28/622 reads (5%) | called by muse, mutect2
- DIO3 | c.240C>T p.P80= | Silent (SNP) | VAF 71/640 reads (11%) | catalogued as rs768427620; called by muse, mutect2, varscan2
- DNAH7 | c.11178A>G p.L3726= | Silent (SNP) | VAF 33/396 reads (8%) | catalogued as rs756015292; called by muse, mutect2
- EFCC1 | c.1143C>T p.D381= | Silent (SNP) | VAF 27/383 reads (7%) | catalogued as rs753141632, COSV71402113; called by muse, mutect2
- IL2RB | c.9C>T p.A3= | Silent (SNP) | VAF 36/354 reads (10%) | catalogued as rs1244437871; called by muse, mutect2, varscan2
- KCNV1 | c.39G>A p.L13= | Silent (SNP) | VAF 53/576 reads (9%) | called by muse, mutect2
- L1CAM | c.633C>A p.A211= | Silent (SNP) | VAF 24/592 reads (4%) | catalogued as COSV62827075; called by muse, mutect2
- LOXL3 | c.1077C>T p.G359= | Silent (SNP) | VAF 37/326 reads (11%) | catalogued as rs752476018, COSV51206548; called by muse, varscan2
- LRP2 | c.8217C>T p.H2739= | Silent (SNP) | VAF 15/252 reads (6%) | called by muse, mutect2
- MAMSTR | c.1026G>A p.P342= (on ENST00000318083 / NM_001130915.2; = p.P239= on NM_182574.2) | Silent (SNP) | VAF 58/700 reads (8%) | catalogued as rs935776445; called by muse, mutect2
- MYH3 | c.3300A>T p.T1100= | Silent (SNP) | VAF 30/440 reads (7%) | called by muse, mutect2
- NPNT | c.753G>T p.L251= | Silent (SNP) | VAF 17/209 reads (8%) | called by muse, mutect2
- PCDHA13 | c.1515G>A p.S505= | Silent (SNP) | VAF 72/797 reads (9%) | called by muse, mutect2
- PKD2 | c.1785A>G p.K595= | Silent (SNP) | VAF 40/486 reads (8%) | catalogued as COSV52941617; called by muse, mutect2
- PLSCR4 | c.558C>T p.I186= | Silent (SNP) | VAF 42/498 reads (8%) | called by muse, mutect2
- R3HDM2 | c.963A>G p.K321= | Silent (SNP) | VAF 44/497 reads (9%) | called by muse, mutect2
- RMND1 | c.501C>T p.N167= | Silent (SNP) | VAF 40/332 reads (12%) | catalogued as rs374790732; ClinVar: likely benign; called by muse, mutect2, varscan2
- SACS | c.8665C>T p.L2889= | Silent (SNP) | VAF 57/634 reads (9%) | catalogued as rs1320208817; called by muse, mutect2
- SCN11A | c.2424C>T p.A808= | Silent (SNP) | VAF 39/237 reads (16%) | called by muse, mutect2, varscan2
- SCYL1 | c.1674C>T p.S558= | Silent (SNP) | VAF 47/429 reads (11%) | catalogued as rs1297933573; called by muse, mutect2, varscan2
- SDK2 | c.5106C>T p.A1702= | Silent (SNP) | VAF 48/444 reads (11%) | called by muse, mutect2, varscan2
- SHROOM2 | c.1743G>A p.P581= | Silent (SNP) | VAF 75/698 reads (11%) | catalogued as rs1425007128, COSV101098659; called by muse, mutect2, varscan2
- SLFN14 | c.2625C>T p.V875= | Silent (SNP) | VAF 44/425 reads (10%) | catalogued as rs1418650340; called by muse, mutect2, varscan2
- SYNPO2 | c.639C>T p.G213= | Silent (SNP) | VAF 42/421 reads (10%) | called by muse, mutect2
- TRPV2 | c.582C>T p.C194= | Silent (SNP) | VAF 40/440 reads (9%) | catalogued as rs771199457; called by muse, mutect2
- UNCX | c.405C>T p.R135= | Silent (SNP) | VAF 16/474 reads (3%) | catalogued as COSV60333720; called by muse, mutect2
- ZFAND3 | c.561C>A p.P187= | Silent (SNP) | VAF 27/386 reads (7%) | catalogued as COSV54730151; called by muse, mutect2
- ZNF469 | c.11160C>T p.S3720= (on ENST00000437464; = p.S3748= on NM_001367624.2) | Silent (SNP) | VAF 21/697 reads (3%) | catalogued as rs936296523; ClinVar: likely benign; called by muse, mutect2
- ZNF865 | c.1050C>T p.F350= | Silent (SNP) | VAF 74/874 reads (8%) | catalogued as rs1245991168; called by muse, mutect2
- ZSWIM3 | c.780C>A p.T260= | Silent (SNP) | VAF 20/436 reads (5%) | catalogued as COSV54846234; called by muse, mutect2
- MRPL21 | c.553+89C>T | Intron (SNP) | VAF 66/682 reads (10%) | catalogued as rs763268818; called by muse, mutect2
- SH2B1 | c.1898-252G>T | Intron (SNP) | VAF 54/542 reads (10%) | catalogued as rs769627655, COSV100450920; called by muse, mutect2, varscan2
- SPOCK1 | c.*656C>T | 3'UTR (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
